Somatic mutation profile of tumor specimen BA2982D (aliquot aq-BA2982D) from BEATAML1.0 case 2474, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with inv(3)(q21q26.2) or t(3;3)(q21;q26.2), RPN1-EVI1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.3 years (26,422 days).
Specimen BA2982D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 416eaa56-ebdd-416b-8f8b-d1862ae934d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2192D (Solid Tissue Normal), aliquot aq-BA2192D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe80b439-1085-4bd6-87a1-d7267062c546

The open-access MAF lists 36 somatic variants for this specimen: 23 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, Intron 3, Splice Site 3, Nonsense Mutation 2, 5'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP1 | c.1146+1G>C p.X382_splice | Splice Site (SNP) | VAF 49/97 reads (51%) | catalogued as rs1559650552, COSV59536271; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AMER3 | c.2516G>A p.R839H | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377081234; called by muse, mutect2, varscan2
- BCAR1 | c.2422G>T p.V808L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV99366125; called by muse, mutect2
- BRWD3 | c.2399G>A p.R800Q | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV100956569; called by muse, mutect2, varscan2
- EGR2 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as COSV104386899; called by muse, mutect2, varscan2
- GSG1L | c.526G>A p.A176T (on ENST00000447459 / NM_001109763.2; = p.A21T on NM_144675.2) | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs762645029, COSV101093972; called by muse, mutect2, varscan2
- IFNLR1 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs146955345; called by muse, mutect2, varscan2
- OR4F15 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.145); catalogued as rs140140871; called by muse, mutect2, varscan2
- PNMA2 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV72908538; called by muse, mutect2
- RUNX1 | c.212_215dup p.S73Lfs*39 (on ENST00000344691 / NM_001001890.3; = p.S100Lfs*39 on NM_001754.5) | Frame Shift Ins (INS) | VAF 66/142 reads (46%) | catalogued as COSV55873881; called by mutect2, pindel, varscan2
- SSC5D | c.2618G>C p.G873A | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1568480139; called by mutect2, varscan2
- SSX5 | c.229G>A p.A77T (on ENST00000347757 / NM_175723.1; = p.A118T on NM_021015.4) | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs200600341, COSV61255302, COSV61255941; called by muse, varscan2
- TEX13C | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1359493276; called by muse, mutect2, varscan2
- WSCD2 | c.607C>T p.R203* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as rs1335158403; called by muse, mutect2, varscan2
- ACKR1 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- GATA2 | c.964T>A p.Y322N | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GTF3C3 | c.536-1G>T p.X179_splice | Splice Site (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- HNRNPUL2 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- NRP2 | c.665-2_672del p.X222_splice | Splice Site (DEL) | VAF 40/170 reads (24%) | called by mutect2, pindel, varscan2
- PRR9 | c.22T>A p.C8S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2
- PRRC2A | c.637C>A p.R213S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2
- SACS | c.4975G>T p.V1659F | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- TENM2 | c.4070G>A p.S1357N (on ENST00000518659 / NM_001122679.2; = p.S1118N on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACYP2 | c.177C>A p.V59= | Silent (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- BRD2 | c.2403C>A p.G801= | Silent (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- GABRA6 | c.855T>C p.T285= | Silent (SNP) | VAF 63/154 reads (41%) | called by muse, mutect2, varscan2
- OR8K5 | c.420G>C p.L140= | Silent (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- RPL9 | c.207C>T p.T69= | Silent (SNP) | VAF 65/144 reads (45%) | catalogued as rs747523284; called by muse, mutect2, varscan2
- SRCAP | c.5683C>A p.R1895= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV52680307; called by muse, mutect2, varscan2
- TIMM50 | c.984G>A p.E328= | Silent (SNP) | VAF 46/92 reads (50%) | catalogued as COSV58680961; called by muse, mutect2, varscan2
- ZPBP2 | c.279G>A p.Q93= (on ENST00000348931 / NM_199321.3; = p.Q71= on NM_198844.3) | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV62375872; called by muse, mutect2, varscan2
- CDC14B | c.161-1310A>G | Intron (SNP) | VAF 41/84 reads (49%) | called by muse, mutect2, varscan2
- DRG1 | c.-18C>A | 5'UTR (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- EYS | c.1767-8003C>T | Intron (SNP) | VAF 12/300 reads (4%) | catalogued as rs1478896551, COSV65459299; called by muse, mutect2
- SLC5A10 | c.-2C>T | 5'UTR (SNP) | VAF 14/34 reads (41%) | catalogued as rs763336465; called by muse, varscan2
- TMEM222 | c.312-597G>A | Intron (SNP) | VAF 46/84 reads (55%) | catalogued as rs777687341; called by muse, mutect2, varscan2
